Somatic mutation profile of tumor specimen TCGA-AB-2819-03B (aliquot TCGA-AB-2819-03B-01W-0728-08) from TCGA case TCGA-AB-2819, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,054 days).
Specimen TCGA-AB-2819-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be2af30c-fa1e-4abd-b7a1-63c1ae5e4b4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2819-11B (Solid Tissue Normal), aliquot TCGA-AB-2819-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae8f14e3-2e1b-42d5-8989-7e47b2c46674

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Ins 2, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAM | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68027009, COSV68037506; called by muse, mutect2, varscan2
- HDAC3 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs950744334, COSV59498060; called by muse, mutect2, varscan2
- HYAL4 | c.759C>G p.N253K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as rs149771586, COSV56140574; called by muse, mutect2, varscan2
- KIT | c.1252_1257del p.Y418_D419del | In Frame Del (DEL) | VAF 16/42 reads (38%) | catalogued as COSV55395410; called by mutect2, pindel*, varscan2
- KMT5B | c.2222delinsGTA p.S741Cfs*4 | Frame Shift Ins (INS) | VAF 23/145 reads (16%) | catalogued as COSV100430394, COSV58569833; called by mutect2*, pindel, varscan2*
- PCDHB3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as rs564746714, COSV50638457; called by muse, mutect2, varscan2
- PDGFRB | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs541926152, COSV55799968; called by muse, varscan2
- POSTN | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1177659142, COSV65711766; called by muse, mutect2, varscan2
- PRUNE2 | c.6452G>A p.R2151Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780026396, COSV65038828; called by muse, mutect2, varscan2
- RGL1 | c.2191C>T p.R731C (on ENST00000360851 / NM_001297672.2; = p.R766C on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778337823, COSV58997266; called by muse, mutect2, varscan2
- ZNF142 | c.4648C>T p.Q1550* (on ENST00000411696 / NM_001379660.1; = p.Q1350* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV68746007; called by muse, mutect2, varscan2
- ASXL2 | c.1286_1287insCTTAACC p.E430Lfs*5 | Frame Shift Ins (INS) | VAF 86/289 reads (30%) | called by mutect2, pindel, varscan2
- KDM6A | c.2162_2171delinsTCCCCTGG p.S721Ffs*8 | Frame Shift Del (DEL) | VAF 31/69 reads (45%) | called by pindel, varscan2*
- ADAM19 | c.1791C>A p.I597= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as COSV57440504; called by muse, mutect2, varscan2
- ARHGEF10L | c.1191C>T p.F397= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs142153324, COSV51441722; called by muse, varscan2
- EHHADH | c.1833A>G p.P611= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs1375826424, COSV51633865; called by muse, mutect2, varscan2
- PCDH19 | c.1104C>T p.I368= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV55272487; called by muse, mutect2, varscan2
- TRA2B | c.312C>T p.R104= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV52026501; called by muse, mutect2, varscan2
